Somatic mutation profile of tumor specimen 4cab24a5-70d4-4364-a2be-da0d99 (aliquot 4cab24a5-70d4-4364-a2be-da0d99_D6_1) from CPTAC case 05BR031, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 46.5 years (17,002 days).
Specimen 4cab24a5-70d4-4364-a2be-da0d99: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1edaad35-afb5-450a-af61-06137c613187.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0b9c8570-2765-42db-9ad7-696943 (Blood Derived Normal), aliquot 0b9c8570-2765-42db-9ad7-696943_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08c9df3a-295a-4fa7-965b-feda8d8b187a

The open-access MAF lists 108 somatic variants for this specimen: 68 protein-altering or splice-affecting, 26 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 26, Nonsense Mutation 7, Intron 5, 3'UTR 4, 5'UTR 3, Splice Region 3, Frame Shift Del 2, In Frame Del 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 32/155 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs560908915; called by muse, mutect2
- ADAD1 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.167); catalogued as COSV99635761, COSV99636211; called by muse, mutect2, varscan2
- ADAMTS20 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs531290635, COSV101239486, COSV67131269; called by muse, mutect2
- BAZ1A | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV62410268; called by muse, mutect2, varscan2
- BMX | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs1189561826; called by muse, mutect2, varscan2
- BOD1L1 | c.5752G>A p.E1918K | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV50008203; called by muse, mutect2, varscan2
- CFAP47 | c.9012G>C p.K3004N | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV66216886; called by muse, mutect2, varscan2
- CHRNB4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1369287083; called by muse, mutect2, varscan2
- DAXX | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 64/303 reads (21%) | catalogued as COSV56472374, COSV56474558; called by muse, mutect2, varscan2
- DMXL1 | c.367A>T p.S123C | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as rs146514647; called by muse, mutect2, varscan2
- FLYWCH1 | c.1091C>T p.T364M (on ENST00000253928 / NM_001308068.2; = p.T363M on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/449 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as rs768508975; called by muse, mutect2, varscan2
- GLI3 | c.4585C>T p.Q1529* | Nonsense Mutation (SNP) | VAF 57/256 reads (22%) | catalogued as COSV67886112; called by muse, mutect2, varscan2
- IL12RB2 | c.2002G>C p.D668H | Missense Mutation (SNP) | VAF 121/314 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024536, COSV99255076; called by muse, mutect2, varscan2
- MIA3 | c.4915G>C p.E1639Q | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs751873073; called by muse, mutect2
- NIBAN2 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs549746967, COSV64823552; called by muse, mutect2, varscan2
- PCDHA12 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 60/750 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV56547382; called by muse, mutect2
- PEAK1 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV100433267, COSV100433603; called by muse, mutect2, varscan2
- PPP2R1A | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV59044382; called by muse, mutect2, varscan2
- PRAMEF1 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as rs779715494, COSV100179654; called by muse, mutect2, varscan2
- PRDM11 | c.1262C>T p.S421L (on ENST00000530656 / NM_001359633.1; = p.S387L on NM_001256695.1) | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.806); catalogued as rs558127362, COSV55444107; called by muse, mutect2, varscan2
- RPS20 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99155124; called by muse, mutect2, varscan2
- SLC12A1 | c.2376G>C p.E792D | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as CD077435, COSV101118159; called by muse, mutect2, varscan2
- SPNS2 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs745328645; called by muse, mutect2, varscan2
- SSTR5 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs748389375; called by muse, mutect2, varscan2
- WDR62 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 131/693 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs4805157; called by muse, mutect2, varscan2
- ZNF711 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV52154543; called by muse, mutect2, varscan2
- AC004922.1 | c.1407C>G p.I469M | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACADSB | c.306G>A p.L102= | Splice Region (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2, varscan2
- APOB | c.10493G>C p.G3498A | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.101); called by muse, mutect2
- ATAD2 | c.3809G>T p.C1270F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2
- ATG2A | c.2633C>G p.S878* | Nonsense Mutation (SNP) | VAF 18/268 reads (7%) | called by muse, mutect2
- CAMSAP2 | c.3823G>A p.E1275K (on ENST00000236925 / NM_001297707.2; = p.E1264K on NM_203459.3) | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CASTOR2 | c.916C>G p.H306D | Missense Mutation (SNP) | VAF 82/533 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- CCDC110 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CCDC77 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.085); called by muse, mutect2
- CHRNA7 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- CNGA2 | c.1912A>T p.T638S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRIM1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CYLC2 | c.974A>G p.K325R | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DIAPH2 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EIF2AK4 | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- FARP2 | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FERMT2 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- GPKOW | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HLA-V | n.352C>G | Splice Region (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- INTS3 | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KCNT2 | c.1432C>A p.Q478K | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KMT2C | c.7310del p.P2437Lfs*15 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- MKI67 | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, varscan2
- MLPH | c.529_540del p.A177_Q180del | In Frame Del (DEL) | VAF 76/320 reads (24%) | called by mutect2, varscan2
- MRPS11 | c.412-6C>G | Splice Region (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2
- MTCP1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MTRF1L | c.835T>A p.S279T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOLC1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NXN | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3C3 | c.1361C>G p.S454C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- POLR3B | c.2026C>A p.H676N | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- PRKDC | c.5803G>T p.E1935* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- PSD4 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- RAD21L1 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SERPINE2 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SMG1 | c.7107G>C p.E2369D | Missense Mutation (SNP) | VAF 145/360 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SYT1 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUT4 | c.4120G>C p.E1374Q | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF592 | c.99_114del p.S34Vfs*28 | Frame Shift Del (DEL) | VAF 28/322 reads (9%) | called by mutect2, pindel
- ZNF729 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.068); called by muse, mutect2
- ANKRD36C | c.3639G>A p.K1213= | Silent (SNP) | VAF 32/221 reads (14%) | called by muse, mutect2, varscan2
- CLIP1 | c.4164C>T p.H1388= (on ENST00000620786 / NM_001247997.1; = p.H1377= on NM_002956.2) | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs989829701; called by muse, mutect2, varscan2
- DCAF4L2 | c.27C>T p.L9= | Silent (SNP) | VAF 35/197 reads (18%) | catalogued as rs748253968; called by muse, mutect2, varscan2
- EVC | c.1881T>G p.T627= | Silent (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- FGF23 | c.642G>A p.E214= | Silent (SNP) | VAF 27/214 reads (13%) | called by muse, mutect2, varscan2
- HCRTR2 | c.525C>T p.I175= | Silent (SNP) | VAF 42/231 reads (18%) | catalogued as COSV63794554; called by muse, mutect2, varscan2
- IGHMBP2 | c.2250C>G p.L750= | Silent (SNP) | VAF 73/469 reads (16%) | catalogued as rs771795171; called by muse, mutect2, varscan2
- ILRUN | c.501C>G p.L167= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- IRF1 | c.195C>T p.Y65= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV55377511; called by muse, mutect2, varscan2
- KCNJ6 | c.744G>A p.S248= | Silent (SNP) | VAF 54/248 reads (22%) | catalogued as rs370165848; called by muse, mutect2, varscan2
- KDM1B | c.2166G>A p.V722= (on ENST00000449850; = p.V489= on NM_153042.4) | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2
- KMT2C | c.13074G>A p.K4358= | Silent (SNP) | VAF 23/218 reads (11%) | catalogued as rs545120533; called by muse, mutect2
- ME1 | c.1356C>A p.G452= | Silent (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- MTF2 | c.642G>A p.L214= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1341281771; called by muse, mutect2
- OR6N1 | c.747C>G p.L249= | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as COSV58649134; called by muse, varscan2
- PCNT | c.6231G>A p.L2077= | Silent (SNP) | VAF 37/359 reads (10%) | catalogued as COSV64028908; called by muse, mutect2, varscan2
- PDE1A | c.93G>A p.L31= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- PPARGC1B | c.105C>T p.L35= | Silent (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- PRKCA | c.60C>T p.F20= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as rs1432138923, COSV52583607; called by muse, mutect2, varscan2
- SLC3A1 | c.1062G>A p.Q354= | Silent (SNP) | VAF 46/367 reads (13%) | catalogued as rs769520920, COSV99577872; called by muse, mutect2, varscan2
- SLC7A8 | c.990T>G p.V330= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- THBS4 | c.159C>T p.P53= | Silent (SNP) | VAF 47/282 reads (17%) | catalogued as rs775493782; called by muse, mutect2, varscan2
- TIE1 | c.2592G>A p.K864= | Silent (SNP) | VAF 154/495 reads (31%) | called by muse, mutect2, varscan2
- TTC6 | c.213G>A p.K71= (on ENST00000267368; = p.K1340= on NM_001310135.3) | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
- USP8 | c.591C>T p.I197= | Silent (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- ZNF521 | c.1731G>A p.L577= | Silent (SNP) | VAF 15/283 reads (5%) | catalogued as rs1183710287; called by muse, mutect2
- CYP27A1 | c.1263+32G>A | Intron (SNP) | VAF 86/560 reads (15%) | called by muse, mutect2, varscan2
- DPP9 | c.2245-30C>T | Intron (SNP) | VAF 17/158 reads (11%) | called by mutect2, varscan2
- FMR1 | c.*938G>C | 3'UTR (SNP) | VAF 36/338 reads (11%) | called by mutect2, varscan2
- IGFALS | c.*156C>G | 3'UTR (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- JPH3 | chr16:87702351 G>A | 3'Flank (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- PEBP1 | c.-4C>T | 5'UTR (SNP) | VAF 80/445 reads (18%) | catalogued as rs542673479; called by muse, mutect2, varscan2
- PRR14 | c.1407-17C>T | Intron (SNP) | VAF 15/294 reads (5%) | called by muse, mutect2
- RGS4 | c.-111G>A | 5'UTR (SNP) | VAF 119/385 reads (31%) | called by muse, mutect2, varscan2
- RUFY1 | c.1026+469G>C | Intron (SNP) | VAF 14/137 reads (10%) | catalogued as COSV60158915; called by muse, mutect2
- SLC9A8 | c.535-46T>G | Intron (SNP) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- SP9 | c.-23C>T | 5'UTR (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- TRIM56 | c.*2141C>G | 3'UTR (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- VPS16 | chr20:2840744 C>T | 5'Flank (SNP) | VAF 41/289 reads (14%) | catalogued as rs1485738250, COSV100642930; called by muse, mutect2, varscan2
- XIRP2 | c.*562G>C | 3'UTR (SNP) | VAF 28/167 reads (17%) | catalogued as rs1324720878; called by muse, mutect2, varscan2
